CCDI case PBCAZF — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3a6e296f-28a2-4b0e-8d48-9fafc212ffde

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.7 years (3,188 days).

Biospecimens (3 samples)
- Sample 0DN1B5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN1BU: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DN1D3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
